Somatic mutation profile of tumor specimen TCGA-DD-AADC-01A (aliquot TCGA-DD-AADC-01A-11D-A40R-10) from TCGA case TCGA-DD-AADC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 53.5 years (19,527 days).
Specimen TCGA-DD-AADC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb08fe59-82bb-4fac-ba5b-3ee7b7458f73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADC-10A (Blood Derived Normal), aliquot TCGA-DD-AADC-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58bda85a-d19d-4745-825e-2253aa59755f

The open-access MAF lists 90 somatic variants for this specimen: 72 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 17, Frame Shift Ins 5, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 57/166 reads (34%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 28/55 reads (51%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ARFGEF3 | c.3017A>G p.H1006R | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs766579661, COSV99293513; called by muse, mutect2, varscan2
- CAST | c.75dup p.H26Tfs*11 (on ENST00000341926; = p.H109Tfs*11 on NM_001750.7 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 36/79 reads (46%) | catalogued as rs1324899428; called by mutect2, pindel, varscan2
- CD302 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52032996; called by muse, mutect2, varscan2
- CELSR3 | c.8506T>C p.S2836P | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV99373537; called by muse, mutect2, varscan2
- CNTN3 | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99724467; called by muse, mutect2, varscan2
- COG5 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.028); catalogued as COSV99772146; called by muse, mutect2, varscan2
- COL2A1 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV100476482; called by muse, mutect2, varscan2
- CRB3 | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV100375302, COSV57569323; called by muse, mutect2, varscan2
- DAGLA | c.3011C>A p.T1004K | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV57195468, COSV99944386; called by muse, mutect2, varscan2
- DCHS1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs184561385; called by muse, mutect2, varscan2
- DDX20 | c.2251C>A p.Q751K | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV100862139; called by muse, mutect2, varscan2
- DENND4C | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs771194757, COSV66823218; called by muse, mutect2, varscan2
- DNAH8 | c.9608T>C p.M3203T | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV100545357; called by muse, mutect2, varscan2
- DSC3 | c.1047T>G p.N349K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100844604; called by muse, mutect2, varscan2
- EDN1 | c.527A>C p.Q176P | Missense Mutation (SNP) | VAF 143/317 reads (45%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.029); catalogued as rs1316232630, COSV101040372; called by muse, mutect2, varscan2
- EMP2 | c.170-1G>T p.X57_splice | Splice Site (SNP) | VAF 40/102 reads (39%) | catalogued as COSV100852808; called by muse, mutect2, varscan2
- ENTR1 | c.752A>G p.D251G (on ENST00000357365 / NM_001039707.2; = p.D228G on NM_006643.4) | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV100048182; called by muse, mutect2, varscan2
- FLG | c.8249C>G p.S2750C | Missense Mutation (SNP) | VAF 81/383 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100911591; called by muse, mutect2, varscan2
- GATAD2B | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 81/160 reads (51%) | catalogued as COSV100897874; called by muse, mutect2, varscan2
- GOLIM4 | c.1042A>G p.M348V | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs760076177, COSV100463004; called by muse, mutect2, varscan2
- INPP5A | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs374027590; called by muse, mutect2, varscan2
- ITGA6 | c.2839C>G p.Q947E (on ENST00000442250; = p.Q908E on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/363 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.253); catalogued as COSV99905537; called by muse, mutect2, varscan2
- JPH4 | c.455C>A p.A152E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV62508145; called by muse, mutect2
- KANK1 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100619762; called by muse, mutect2, varscan2
- KIAA0100 | c.5551C>G p.L1851V | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101197317; called by muse, mutect2, varscan2
- KIRREL3 | c.1033C>T p.L345F | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.718); catalogued as COSV101585730; called by muse, mutect2, varscan2
- MED13L | c.5665A>G p.M1889V | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV99928860; called by muse, mutect2, varscan2
- MPV17L | c.409C>T p.Q137* (on ENST00000396385 / NM_001128423.2; = p.T113I on NM_173803.4) | Nonsense Mutation (SNP) | VAF 39/95 reads (41%) | catalogued as rs753612895, COSV99806206; called by muse, mutect2, varscan2
- MUC5B | c.4529C>A p.T1510K | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101500346, COSV71592123; called by muse, mutect2, varscan2
- MYH13 | c.5617G>A p.D1873N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as rs749510137, COSV99354011; called by muse, mutect2, varscan2
- NAV3 | c.3845T>C p.L1282S | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99891036; called by muse, mutect2, varscan2
- NDUFV2 | c.95A>G p.N32S | Missense Mutation (SNP) | VAF 100/366 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100571716; called by muse, mutect2
- NKPD1 | c.1537G>T p.D513Y | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100521578; called by muse, mutect2, varscan2
- NLRP14 | c.1352G>T p.G451V | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100204987; called by muse, mutect2, varscan2
- NR3C2 | c.2014+1G>T p.X672_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100679088; called by muse, mutect2, varscan2
- NRG3 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV64577322; called by muse, mutect2, varscan2
- PCNT | c.8489G>T p.C2830F | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.687); catalogued as COSV100855508; called by muse, mutect2, varscan2
- PCYT1A | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.264); catalogued as COSV99492155; called by muse, mutect2, varscan2
- PER1 | c.1825G>T p.A609S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV100424560; called by mutect2, varscan2
- PGAP1 | c.1433C>G p.S478C | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV100698197; called by muse, mutect2, varscan2
- PLD2 | c.1522G>A p.G508S | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV99562359; called by muse, mutect2, varscan2
- PLXNB3 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 69/92 reads (75%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as COSV100737456; called by muse, mutect2, varscan2
- PON3 | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99672492; called by muse, mutect2, varscan2
- PROK2 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99816949; called by muse, mutect2, varscan2
- PSG3 | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 83/137 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100548981; called by muse, mutect2, varscan2
- PSIP1 | c.1012A>T p.K338* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV101050944; called by muse, mutect2, varscan2
- PUF60 | c.499A>G p.M167V (on ENST00000526683 / NM_001362896.2; = p.M150V on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/187 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.374); catalogued as COSV100253309; called by muse, mutect2, varscan2
- RAPGEF1 | c.1864G>C p.A622P | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1271567352, COSV100940584, COSV64698015; called by muse, mutect2
- RPL18A | c.184G>T p.V62F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99714422; called by muse, mutect2, varscan2
- RTL10 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs9618711; called by muse, mutect2, varscan2
- SDCCAG8 | c.1864G>T p.A622S | Missense Mutation (SNP) | VAF 127/364 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV100654256; called by muse, mutect2, varscan2
- SLC25A22 | c.70A>T p.T24S | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.714); catalogued as COSV100204202; called by muse, mutect2, varscan2
- SLC29A1 | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV100505798; called by muse, mutect2, varscan2
- SLC46A1 | c.894C>A p.C298* | Nonsense Mutation (SNP) | VAF 133/265 reads (50%) | catalogued as COSV100398097; called by muse, mutect2, varscan2
- SPECC1 | c.2315G>A p.G772D | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV99822018; called by muse, mutect2, varscan2
- ST8SIA5 | c.407C>A p.T136N | Missense Mutation (SNP) | VAF 56/105 reads (53%) | PolyPhen benign (0.026); catalogued as COSV100164719, COSV59335769; called by muse, mutect2, varscan2
- SULF2 | c.370A>G p.S124G | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV100737202; called by muse, mutect2, varscan2
- TEX14 | c.218A>T p.D73V | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53623002, COSV99542276; called by muse, mutect2, varscan2
- TLR8 | c.2858G>C p.S953T (on ENST00000218032 / NM_138636.5; = p.S971T on NM_016610.4) | Missense Mutation (SNP) | VAF 305/381 reads (80%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.622); catalogued as COSV99487027; called by muse, mutect2, varscan2
- TMEM68 | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100588113; called by muse, mutect2, varscan2
- TNN | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 278/562 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs199634558; called by muse, mutect2, varscan2
- UGP2 | c.1252A>C p.M418L | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.123); catalogued as COSV100451618; called by muse, mutect2, varscan2
- VWCE | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57113544; called by muse, mutect2, varscan2
- ZBTB18 | c.1075G>T p.V359F | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100700130, COSV62397748; called by muse, mutect2, varscan2
- ZNF208 | c.1321A>G p.M441V | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV101237025; called by muse, mutect2, varscan2
- ATR | c.6250dup p.Y2084Lfs*13 | Frame Shift Ins (INS) | VAF 27/105 reads (26%) | called by mutect2, pindel, varscan2
- PHF20L1 | c.106dup p.I36Nfs*2 | Frame Shift Ins (INS) | VAF 88/279 reads (32%) | called by mutect2, pindel, varscan2
- ZNF227 | c.540del p.N180Kfs*4 | Frame Shift Del (DEL) | VAF 78/154 reads (51%) | called by mutect2, varscan2
- ZNF579 | c.107dup p.A37Rfs*5 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | called by mutect2, varscan2
- ZNF638 | c.663del p.D222Ifs*36 | Frame Shift Del (DEL) | VAF 34/142 reads (24%) | called by mutect2, pindel, varscan2
- ACTR3B | c.411A>G p.P137= | Silent (SNP) | VAF 77/277 reads (28%) | catalogued as rs756388974, COSV99754069; called by muse, varscan2
- CNBD1 | c.357T>C p.H119= | Silent (SNP) | VAF 135/713 reads (19%) | catalogued as COSV101572867; called by muse, mutect2, varscan2
- CPAMD8 | c.4053G>A p.A1351= (on ENST00000651564; = p.A1304= on NM_015692.5) | Silent (SNP) | VAF 54/101 reads (53%) | catalogued as rs757256301, COSV71597540; called by muse, mutect2, varscan2
- DCAF4L2 | c.348G>T p.P116= | Silent (SNP) | VAF 33/161 reads (20%) | catalogued as COSV100150901, COSV60477312; called by muse, mutect2, varscan2
- GPR101 | c.1275G>A p.V425= | Silent (SNP) | VAF 47/61 reads (77%) | catalogued as COSV99981426; called by muse, mutect2, varscan2
- LRP12 | c.1956T>C p.S652= | Silent (SNP) | VAF 96/156 reads (62%) | catalogued as COSV99407744; called by muse, mutect2, varscan2
- NUP210 | c.1770G>T p.V590= | Silent (SNP) | VAF 71/200 reads (36%) | catalogued as rs767996831, COSV99596216; called by muse, mutect2, varscan2
- PCDHB13 | c.1578G>T p.G526= | Silent (SNP) | VAF 184/278 reads (66%) | catalogued as rs34902137, COSV99507281; called by muse, varscan2
- PDZD2 | c.3807A>G p.A1269= | Silent (SNP) | VAF 50/334 reads (15%) | catalogued as rs1218627314, COSV99224993; called by muse, mutect2
- PHACTR2 | c.1014C>T p.P338= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as rs200488499, COSV99991599; called by muse, mutect2, varscan2
- PPP2R5E | c.543A>G p.V181= | Silent (SNP) | VAF 57/186 reads (31%) | catalogued as COSV100518610; called by muse, mutect2, varscan2
- RASIP1 | c.1299C>T p.I433= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as COSV99710774; called by muse, varscan2
- RREB1 | c.2076G>T p.T692= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV58560782; called by muse, mutect2, varscan2
- RYR1 | c.11842A>C p.R3948= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV100615747; called by muse, mutect2, varscan2
- STON2 | c.2226C>T p.T742= (on ENST00000649389 / NM_001366849.2; = p.T685= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/144 reads (63%) | catalogued as COSV50851505, COSV99964746; called by muse, mutect2, varscan2
- VPS54 | c.1036T>C p.L346= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99708141; called by muse, mutect2, varscan2
- ZNF672 | c.669G>C p.G223= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100129201, COSV60638512; called by muse, mutect2, varscan2
- AMELX | c.103-129C>G | Intron (SNP) | VAF 84/204 reads (41%) | catalogued as COSV100498121; called by muse, mutect2, varscan2
